Gene-level copy-number profile of tumor specimen TCGA-AO-A12G-01A from TCGA case TCGA-AO-A12G, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.9 years (27,705 days).
Specimen TCGA-AO-A12G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4a2c3e4c-941a-4d08-9d30-386ac70cd657.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A12G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ad20af69-d9fe-4bc2-a6f4-623953a551a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,247; copy number 2: 41,671; copy number 3: 5,178; copy number 4: 1,777; copy number 5: 1,459; copy number 6: 190; copy number 7: 175; copy number 8: 11; copy number 10: 29; copy number 11: 6; copy number 13: 21; copy number 14: 16; copy number 18: 27; copy number 20: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A12G-01A-11D-A10L-01): tumor purity 0.68, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,943 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,784,125–119,391,829, 220 genes, copy number 6–20 (broad region; genes not listed).
- chr7:10,449,820–10,779,944, 1 gene, copy number 6 (within-gene range 1–10): MGC4859.
- chr7:10,702,676–15,842,360, 46 genes, copy number 6: AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1.
- chr7:16,208,945–16,270,604, 2 genes, copy number 6 (within-gene range 4–6): RPL36AP29, CRPPA-AS1.
- chr7:41,667,168–44,198,170, 54 genes, copy number 5–7 (within-gene range 4–7): INHBA, INHBA-AS1, GLI3, HMGN2P30, LINC01448, TCP1P1, AC010132.1, AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32, AC005537.1, Y_RNA, HECW1, HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P, AC004692.2, AC004692.1, LUARIS, STK17A, COA1, BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK.
- chr7:46,890,625–47,079,128, 5 genes, copy number 7: AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1.
- chr7:48,660,125–49,259,846, 8 genes, copy number 7: AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2.
- chr8:51,257,688–145,066,685, 1,457 genes, copy number 5 (broad region; genes not listed).
- chr9:124,862,130–125,438,509, 17 genes, copy number 6–7: ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2, PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1, Metazoa_SRP, AL359632.1.
- chr9:126,057,580–127,980,989, 53 genes, copy number 6–18: AL589923.1, AL162391.2, AL162391.1, MVB12B, NRON, SNORD116, AL356309.2, AL356309.3, AL356309.1, AL161908.1, LMX1B, AL161908.2, AL161731.1, ZBTB43, ZBTB34, RALGPS1, ANGPTL2, AL450263.1, GARNL3, AL450263.2, AL445222.1, SLC2A8, ZNF79, RPL12, SNORA65, LRSAM1, Y_RNA, NIBAN2, STXBP1, AL162426.1, PTRH1, MIR3911, CFAP157, TTC16, TOR2A, SH2D3C, AL162586.2, CDK9, MIR3960, MIR2861, FPGS, ENG, AL162586.1, RNA5SP296, AK1, AL157935.2, MIR4672, ST6GALNAC6, ST6GALNAC4, PIP5KL1, AL157935.1, DPM2, FAM102A.
- chr11:76,349,956–78,582,156, 64 genes, copy number 7–13 (broad region; genes not listed).
- chr11:84,936,689–86,069,882, 16 genes, copy number 14 (within-gene range 1–14): AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM.

Autosomal genes at a single copy (total copy number 1): 9,023. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
